Surgical pathology report (de-identified scan), TCGA case TCGA-XF-A9T2, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site University of Southern California, specimen TCGA-XF-A9T2-01A (Primary Tumor).

[page 1 of 6]
Collected
Ordered by

DIAGNOSIS:

RADICAL CYSTECTOMY, BILATERAL PELVIC LYMPH NODES DISSECTION

RIGHT DISTAL URETER (A):

FROZEN SECTION DIAGNOSIS:

- NEGATIVE

FINAL DIAGNOSIS:

- BENIGN URETER

- NO DYSPLASIA OR CARCINOMA IDENTIFIED

LEFT DISTAL URETER (B):

FROZEN SECTION DIAGNOSIS:

- FOCAL HIGH GRADE DYSPLASIA

FINAL DIAGNOSIS:

- BENIGN URETER ON PERMANENT SECTION

- NO DYSPLASIA OR CARCINOMA IDENTIFIED

MARGIN #2, LEFT URETER (C):

FROZEN SECTION DIAGNOSIS:

- NEGATIVE

FINAL DIAGNOSIS:

- BENIGN URETER

- NO DYSPLASIA OR CARCINOMA IDENTIFIED

APICAL URETHRAL MARGIN F/S:

INTRAOPERATIVE FROZEN SECTION DIAGNOSIS:

- NEGATIVE

FINAL DIAGNOSIS:

- BENIGN URETHRAL MUCOSA

- NO HIGH GRADE DYSPLASIA OR CARCINOMA IDENTIFIED

BLADDER/PROSTATE (E):

INTRAOPERATIVE GROSS DIAGNOSIS:

- TUMOR IDENTIFIED IN LEFT BLADDER WALL INFILTRATING THROUGH MUSCULAR
PROPRIA TO THE PERIVESICAL SOFT TISSUE

FINAL DIAGNOSIS:

- BLADDER:

- POORLY DIFFERENTIATED UROTHELIAL CARCINOMA, NUCLEAR GRADE 4/4,
INFILTRATING THROUGH THE MUSCULARIS PROPRIA INTO PERIVESICAL
FAT, BUT NOT AT THE INKED MARGINS (SEE COMMENT)

- LYMPHOVASCULAR INVASION IDENTIFIED

- NO UROTHELIAL CARCINOMA IN SITU (FLAT LESION IDENTIFIED) IDENTIFIED

- ALL SURGICAL MARGINS FREE OF MALIGNANCY

- PROSTATE:

- BILATERAL PROSTATIC ADENOCARCINOMA, GLEASON'S SCORE 6 (3+3)
CONFINED TO THE PROSTATE WITH FOCAL ABUTTING AT THE RIGHT APICAL
MARGIN (<2%)

- THE REMAINING APICAL AND PERIPHERAL PROSTATIC MARGINS, FREE OF
MALIGNANCY

- BILATERAL SEMINAL VESICLES AND VASA DIFFERENTIA, FREE OF
MALIGNANCY

- MULTIFOCAL HIGH GRADE PROSTATIC INTRAEPITHELIAL NEOPLASIA (PIN II-III)

- PROSTATIC ATROPHY WITH FOCAL CHRONIC INFLAMMATION IDENTIFIED

RIGHT PARACAVAL LYMPH NODES (F):

- NO METASTATIC CARCINOMA IDENTIFIED IN 15 LYMPH NODES EXAMINED (0/15)

RIGHT COMMON ILIAC LYMPH NODES (G):

ICD 6-3
Carcinoma, urothelial NOS
812013
Date ^{path} Bladder NOS @67.9
Bladder, lateral wall @67.2
J28/26/14

[page 2 of 6]
Collected

Ordered by

Location

- NO METASTATIC CARCINOMA IDENTIFIED IN SEVEN LYMPH NODES EXAMINED (0/7)

RIGHT PRESACRAL LYMPH NODES (H):

- NO METASTATIC CARCINOMA IDENTIFIED IN FOUR LYMPH NODES EXAMINED (0/4)

RIGHT LYMPH NODES OF CLOQUET (I):

- NO METASTATIC CARCINOMA IDENTIFIED IN THREE LYMPH NODES EXAMINED (0/3)

RIGHT EXTERNAL ILIAC LYMPH NODES (J):

- NO METASTATIC CARCINOMA IDENTIFIED IN 18 LYMPH NODES (0/18)

RIGHT OBTURATOR/HYPOGASTRIC LYMPH NODES (K):

- NO METASTATIC CARCINOMA IDENTIFIED IN SEVEN LYMPH NODES EXAMINED (0/7)

LEFT PARA AORTIC LYMPH NODES (L):

- NO METASTATIC CARCINOMA IDENTIFIED IN NINE LYMPH NODES EXAMINED (0/9)

LEFT COMMON ILIAC LYMPH NODES (M):

- NO METASTATIC CARCINOMA IDENTIFIED IN 19 LYMPH NODES EXAMINED (0/19)

LEFT LYMPH NODES OF CLOQUET (N):

- NO METASTATIC CARCINOMA IDENTIFIED IN FIVE LYMPH NODES EXAMINED (0/5)

LEFT EXTERNAL ILIAC LYMPH NODES (O):

- NO METASTATIC CARCINOMA IDENTIFIED IN 22 LYMPH NODES EXAMINED (0/22)

LEFT OBTURATOR/HYPOGASTRIC LYMPH NODES (P):

- NO METASTATIC CARCINOMA IDENTIFIED IN 18 LYMPH NODES EXAMINED (0/18)

LEFT PRE SCIATIC LYMPH NODES (Q):

- NO METASTATIC CARCINOMA IDENTIFIED IN NINE LYMPH NODES EXAMINED (0/9)

RIGHT PRE SCIATIC LYMPH NODES (R):

- NO METASTATIC CARCINOMA IDENTIFIED IN FIVE LYMPH NODES EXAMINED (0/5)

LEFT PROXIMAL URETER (S):

- BENIGN URETER
- NO DYSPLASIA OR CARCINOMA IDENTIFIED

RIGHT PROXIMAL URETER (T):

- BENIGN URETER
- NO DYSPLASIA OR CARCINOMA IDENTIFIED

TOTAL LYMPH NODES:

- NO METASTATIC CARCINOMA IDENTIFIED IN 141 LYMPH NODES EXAMINED (0/141)

AJCC PATHOLOGIC STAGE (5TH EDITION): T3bN0MX

COMMENT:

Immunohistochemical studies for chromogranin and synaptophysin are negative, which indicates there is no neuroendocrine differentiation of the bladder carcinoma. The

[page 3 of 6]
Collected

Ordered by

Location

case was discussed with

SPECIMEN SOURCE:

A: "Right distal ureter"
B: "Lt. distal ureter"
C: "Margin #2 left ureter"
D: "Apical urethral margin-f/s"
E: "Bladder/prostate"
F: "Rt. para caval L.N."
G: "Rt. common iliac L.N."
H: "Pre sacral L.N."
I: "Rt. L.N. of cloquet"
J: "Rt. external iliac L.N."
K: "Rt. obturator/hypogastric L.N."
L: "Left para aortic L.N."
M: "Lt. common iliac L.N."
N: "Lt. L.N. of cloquet"
O: "Lt. external iliac L.N."
P: "Lt. obturator/hypogastric L.N."
Q: "Lt. pre sciatic L.N."
R: "Rt. pre sciatic L.N."
S: "Lt. proximal ureter"
T: "Rt. proximal ureter"

CLINICAL INFORMATION:

Pre-op Dx: Invasive bladder cancer
Post-op Dx: Same

GROSS EXAMINATION:

A: The specimen is received fresh from the O.R. and labeled "Right distal ureter". It consists of a segment of ureter measuring 0.2 cm in length x 0.3 cm in diameter. The specimen is entirely submitted for frozen section in AFS.

B: The specimen is received fresh from the O.R. and labeled "Lt. distal ureter". It consists of a segment of ureter measuring 0.2 cm in length x 0.3 cm in diameter. The specimen is entirely submitted for frozen section in BFS.

C: The specimen is received fresh from the O.R. and labeled "Margin #2 left ureter". It consists of a segment of ureter measuring 1 cm in length x 0.4 cm in diameter. The specimen is oriented by the surgeon and the club is both at the distal end. The distal end is kept for permanent and the proximal margin is submitted for frozen section in CFS, and the remaining tissue is submitted in one cassette.

D: The specimen is received fresh from the O.R. and labeled "Apical urethral margin-f/s". It consists of red-tan soft tissue fragment measuring 2.5 x 0.5 x 0.2 cm. The specimen is entirely submitted for frozen section in DFS.

E: The specimen is received fresh from the O.R. and labeled "Bladder/prostate". It consists of a radical prostatectomy specimen weighing 422 grams and measuring overall 25 x 12 x 6 cm. The peritoneum measures 19 x 15 x 0.1 cm. It is yellow-pink smooth glistening and unremarkable. The prostate and the lower bladder are entirely inked black. Red ink is superimposed on the right side of prostate. The prostate measures 5.5 x 4.5 x 4 cm. Opening the prostate anteriorly reveals the prostatic urethra to measure 4 cm in length x 3 cm in circumference without excavation. The verumontanum measures 0.7 x 0.5 x 0.3 cm and is unremarkable. The bladder itself measures 6 x 5 x 4 cm. Opening the bladder anteriorly shows an exophytic tumor on the left lateral wall which measures 5.5 x 5 x 4 cm. The tumor extends grossly through the muscle and abut the inked peritoneal margin. The tumor comes within 0.2 cm from the left ureterovesical junction. The attached right

[page 4 of 6]
collected

Ordered by

Location

ureter measures 5 cm in length x 0.5 cm in diameter with normal appearing mucosa. The attached left ureter measures 4 cm in length x 0.5 cm in diameter with normal appearing mucosa. The right seminal vesicle measures 3 x 2 x 0.5, and the left seminal vesicle measure 2.5 x 2 x 0.7 cm and are grossly unremarkable. The right vas deferens measures 3 cm in length x 0.5 cm in diameter and the left vas deferens measures 3.5 cm in length x 0.5 cm in diameter, and are grossly unremarkable. Representative sections are submitted in 34 cassettes.

F: The specimen is received in formalin and labeled "Rt. para caval L.N.". It consists of an aggregate of yellow fatty tissue with probable lymph nodes measuring 3 x 2.5 x 0.5 cm. The specimen is entirely submitted in two cassettes.

G: The specimen is received in formalin and labeled "Rt. common iliac L.N.". It consists of an aggregate of fibrofatty tissue measuring in aggregate 3.5 x 2.5 x 1 cm. The specimen is entirely submitted in three cassettes.

H: The specimen is received in formalin and labeled "Pre sacral L.N.". It consists of fibro tissue fragment measuring 4 x 3 x 2 cm. The specimen is entirely submitted in three cassettes.

I: The specimen is received in formalin and labeled "Rt. L.N. of cloquet". It consists of lymph node with surrounding fat measuring 1.5 x 1 x 0.5 cm. The specimen is bisected and entirely submitted in one cassette.

J: The specimen is received in formalin and labeled "Rt. external iliac L.N.". It consists of multiple fragments of yellow fatty tissue with lymph nodes measuring in aggregate 6.5 x 3.8 x 2.1 cm. The specimen is entirely submitted in six cassettes.

K: The specimen is received in formalin and labeled "Rt. obturator/hypogastric L.N.". It consists of multiple fragments of yellow fatty tissue with lymph nodes measuring in aggregate 7 x 5.5 x 2.5 cm. The specimen is entirely submitted in seven cassettes.

L: The specimen is received in formalin and labeled "Left para aortic L.N.". It consists of multiple fragments of yellow fatty tissue with lymph nodes measuring in aggregate 4.5 x 3.5 x 1.5 cm. The specimen is entirely submitted in three cassettes.

M: The specimen is received in formalin and labeled "Lt. common iliac L.N.". It consists of multiple fragments of yellow fatty tissue with lymph nodes measuring in aggregate 6.5 x 4 x 2.5 cm. The specimen is entirely submitted in six cassettes.

N: The specimen is received in formalin and labeled "Lt. L.N. of cloquet". It consists of one lymph node measuring 2 x 1.5 x 1 cm. The lymph node is serially sectioned and entirely submitted in two cassettes.

O: The specimen is received in formalin and labeled "Lt. external iliac L.N.". It consists of multiple fragments of yellow fatty tissue with lymph nodes measuring in aggregate 6.5 x 4 x 2 cm. The specimen is entirely submitted in six cassettes.

P: The specimen is received in formalin and labeled "Lt. obturator/hypogastric L.N.". It consists of multiple fragments of yellow fatty tissue with lymph nodes measuring in aggregate 8 x 6 x 3 cm. The specimen is entirely submitted in eight cassettes.

Q: The specimen is received in formalin and labeled "Lt. pre sciatic L.N.". It consists of multiple fragments of yellow fatty tissue measuring in aggregate 1.5 x 1 x 0.5 cm. The specimen is entirely submitted in one cassette.

R: The specimen is received in formalin and labeled "Rt. pre sciatic L.N.". It

[page 5 of 6]
Collected

Ordered by

Location

consists of multiple fragments of yellow fatty tissue measuring in aggregate 2.5 x 2 x 1 cm. The specimen is entirely submitted in two cassettes.

S: The specimen is received in formalin and labeled "Lt. proximal ureter". It consists of a segment of ureter measuring 1 cm in length x 0.5 cm in diameter. The specimen is serially sectioned and entirely submitted in one cassette.

T: The specimen is received in formalin and labeled "Rt. proximal ureter". It consists of a segment of ureter measuring 0.6 cm in length x 0.5 cm in diameter. The specimen is serially sectioned and totally submitted in one cassette.

SECTIONS:

AFS: frozen section, right distal ureter
BFS: frozen section, left distal ureter
CFS: frozen section, margin # 2 left ureter; proximal margin
C1: remaining tissue
DFS: apical urethral margin
E1, 2: consecutive section of tumor
E3: tumor with deep inked margin
E4: tumor with left ureterovesical junction
E5-7: tumor with deep inked margin
E8-9: consecutive section of tumor
E10: tumor with deep inked margin
E11: representative section of left anterior wall
E12: representative section of dome
E13: representative section of right anterior wall
E14: representative section of posterior wall
E15: right ureterovesical junction
E16: representative section of trigone
E17, 18: right apex of prostate
E19, 20: left apex of prostate
E21: right anterior distal prostate
E22: right posterior distal prostate
E23: left distal prostate
E24: right anterior mid prostate
E25: right posterior mid prostate
E26: left anterior mid prostate
E27: left posterior mid prostate
E28: right anterior proximal prostate
E29: right posterior proximal prostate
E30: left anterior proximal prostate
E31: left posterior proximal prostate with left seminal vesicle and prostate junction
E32: right seminal vesicle and right vas deferens
E33: left seminal vesicle and left vas deferens
E34: fat for probable lymph node
F1-2: right para caval lymph node
G1-3: right common iliac lymph node
H1-3: pre sacral lymph node
I: right lymph node of Cloquet, bisected
J1-6: right external iliac lymph node
K1-7: right obturator/hypogastric lymph node
L1-3: left para aortic lymph node
M1-6: left common iliac lymph node
N1, 2: left lymph node of Cloquet
O1-6: left external iliac lymph node
P1-6: left obturator/hypogastric lymph node
Q: left pre sciatic lymph node
R1, 2: right pre sciatic lymph node
S: left proximal ureter

[page 6 of 6]
Collected	
Ordered by	Location

T: right proximal ureter

INTRAOPERATIVE FROZEN CONSULTATION:

- AFS: Right distal ureter
- negative
- BFS: Left distal ureter
- focal high-grade dysplasia
- CFS: Margin #2 left ureter
- negative
- DFS: Apical urethral margin
- negative

INTRAOPERATIVE GROSS CONSULTATION

- Bladder (E):
- tumor identified which involves the muscle and abuts the inked margin

MICROSCOPIC EXAMINATION:

A-T. See final microscopic diagnosis.

Criteria	lu 3/12/14	ALCA	Yes	No

Source: NCI Genomic Data Commons file a58d0505-dcbd-47ce-964b-4d3d1575fff2 (TCGA-XF-A9T2.71F04D3B-0CA3-4CB3-9E94-E082F37C4097.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).